Somatic mutation profile of tumor specimen TCGA-A2-A0D1-01A (aliquot TCGA-A2-A0D1-01A-11W-A050-09) from TCGA case TCGA-A2-A0D1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.9 years (28,084 days).
Specimen TCGA-A2-A0D1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22d6b10b-4135-473a-8f01-6cefb8458188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0D1-10A (Blood Derived Normal), aliquot TCGA-A2-A0D1-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e62cabc9-2921-4d81-869e-b1c743dd0137

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 18, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDHA1 | c.483C>T p.Y161= | Silent (SNP) | VAF 72/328 reads (22%) | catalogued as rs398123300, CS080731, COSV63328926; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 67/203 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 160/210 reads (76%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ADGRV1 | c.11626G>T p.E3876* | Nonsense Mutation (SNP) | VAF 82/153 reads (54%) | catalogued as COSV67993090; called by muse, mutect2, varscan2
- ANTXR2 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 33/826 reads (4%) | catalogued as rs750324212, CM066532, COSV56318716; called by muse, mutect2
- BPIFB4 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV64952054; called by muse, mutect2, varscan2
- DCAF4L2 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 220/316 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV60481189; called by muse, mutect2, varscan2
- EPHB1 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV101212747, COSV101213491; called by muse, mutect2
- FMO5 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.434); catalogued as COSV54209771; called by mutect2, varscan2
- HACD1 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100778503; called by muse, mutect2
- HDLBP | c.436A>G p.R146G | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1473316822, COSV60499809; called by muse, mutect2, varscan2
- HELZ | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.4); PolyPhen benign (0.087); catalogued as rs1408699027, COSV62380357; called by muse, mutect2, varscan2
- IDH3G | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.773); catalogued as COSV54209526; called by muse, mutect2, varscan2
- KAT5 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as COSV57730422; called by muse, mutect2
- LARGE2 | c.357del p.M119Ifs*14 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as COSV57686251; called by mutect2, pindel, varscan2
- LRP12 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs776663032, COSV52633337; called by muse, mutect2, varscan2
- MNAT1 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV54194979; called by muse, mutect2, varscan2
- MUC16 | c.7694C>T p.T2565M | Missense Mutation (SNP) | VAF 222/791 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs776081952, COSV67483278; called by muse, mutect2, varscan2
- MYT1L | c.2943G>C p.K981N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67704254; called by muse, mutect2, varscan2
- NAT8 | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV55542950; called by muse, mutect2, varscan2
- NPSR1 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as rs376640561; called by muse, mutect2, varscan2
- NXF3 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.271); catalogued as COSV67704831; called by muse, mutect2, varscan2
- OR2T6 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100861589; called by muse, mutect2
- OR5A1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 239/516 reads (46%) | catalogued as rs199856591, COSV57377870; called by muse, mutect2, varscan2
- PLCL2 | c.2339A>T p.D780V (on ENST00000615277 / NM_001144382.2; = p.D654V on NM_015184.5) | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67624498; called by muse, mutect2, varscan2
- SALL1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs750514153, COSV51760431, COSV51762914; called by muse, mutect2, varscan2
- SEZ6L | c.2837_2844del p.A946Gfs*60 | Frame Shift Del (DEL) | VAF 50/205 reads (24%) | catalogued as COSV50678440; called by mutect2, pindel, varscan2
- SLC9C1 | c.29dup p.S11Qfs*3 | Frame Shift Ins (INS) | VAF 36/60 reads (60%) | catalogued as rs749004401; called by mutect2, varscan2
- SMIM19 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 151/642 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as COSV69327029; called by muse, mutect2, varscan2
- SPAG17 | c.1954A>C p.M652L | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1362025154, COSV60465579; called by muse, mutect2, varscan2
- TGFBI | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.565); catalogued as rs774207585, COSV59353599; called by muse, mutect2, varscan2
- TXK | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV51918784; called by muse, mutect2, varscan2
- UMOD | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56778760; called by muse, mutect2, varscan2
- UNC13B | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 129/295 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs1199217477, COSV65937709; called by muse, mutect2, varscan2
- XCR1 | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58570510; called by muse, mutect2, varscan2
- XYLT1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs146405799; called by muse, mutect2
- ECH1 | c.712del p.L238Wfs*21 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- MMP21 | c.991_1002del p.G331_D334del | In Frame Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel
- UBC | c.1632dup p.I545Hfs*9 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | called by pindel, varscan2
- ACAT2 | c.450T>A p.G150= | Silent (SNP) | VAF 136/253 reads (54%) | catalogued as COSV65454756; called by muse, mutect2, varscan2
- CRY2 | c.600G>A p.E200= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV101314626, COSV69889201; called by muse, mutect2, varscan2
- DDIT4L | c.564A>G p.T188= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV56767926; called by muse, mutect2, varscan2
- HIVEP2 | c.1038C>T p.G346= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV50041199; called by muse, mutect2
- IGF2R | c.4125T>C p.A1375= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV63631932; called by muse, mutect2, varscan2
- KCNA5 | c.334C>T p.L112= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV52908000; called by muse, mutect2, varscan2
- KIAA2026 | c.553C>T p.L185= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs758652566, COSV52390985; called by muse, mutect2, varscan2
- MAML3 | c.987C>T p.F329= | Silent (SNP) | VAF 41/303 reads (14%) | catalogued as COSV59077288; called by muse, mutect2, varscan2
- MKI67 | c.111C>T p.I37= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV64076209; called by muse, mutect2, varscan2
- NF1 | c.5377C>T p.L1793= (on ENST00000358273 / NM_001042492.3; = p.L1772= on NM_000267.3) | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs761676110, COSV62216163; ClinVar: likely benign; called by muse, mutect2
- PDE6A | c.777C>T p.F259= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV54930537; called by muse, mutect2, varscan2
- RNF133 | c.705A>C p.G235= | Silent (SNP) | VAF 98/241 reads (41%) | catalogued as COSV57380439; called by muse, mutect2, varscan2
- SLC7A3 | c.147C>T p.G49= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs368309633, COSV53228951; called by muse, mutect2, varscan2
- TGM1 | c.1569C>T p.I523= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs750955048, COSV52864938; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIE1 | c.2799G>A p.R933= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV65250979; called by muse, mutect2, varscan2
- USP53 | c.636A>G p.L212= | Silent (SNP) | VAF 114/265 reads (43%) | catalogued as rs757557574, COSV56797018; called by muse, mutect2, varscan2
- YTHDF3 | c.114C>T p.Y38= | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as COSV72773813; called by muse, mutect2, varscan2
- RPL4 | c.176-94C>G | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100328455, COSV57182381; called by muse, mutect2, varscan2
- SPDYE5 | c.161-10C>G | Intron (SNP) | VAF 17/168 reads (10%) | called by mutect2, varscan2
